CCDI case PBCEPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/7f560412-0dfa-4c7c-a1a2-f110367a19b7

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 18.6 years (6,798 days).

Biospecimens (3 samples)
- Sample 0DQOEA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQOES: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQOF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
